Somatic mutation profile of tumor specimen 347e379b-77c0-4dd3-aa25-18c9d1 (aliquot 347e379b-77c0-4dd3-aa25-18c9d1_D6) from CPTAC case 01OV026, project CPTAC-2 (Retroperitoneum and peritoneum — Cystic, Mucinous and Serous Neoplasms). Sex at birth: female; Primary diagnosis: Serous adenocarcinoma, NOS; Tissue or organ of origin: Peritoneum, NOS; FIGO stage: Stage IIIC.
Specimen 347e379b-77c0-4dd3-aa25-18c9d1: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d4398422-4943-43e1-9155-19f28896b0f7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 6ad15aed-b0a2-4542-8cd8-4a0682 (Blood Derived Normal), aliquot 6ad15aed-b0a2-4542-8cd8-4a0682_D1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d037b8f1-ae0c-42db-925f-1bed3f15ce4e

The open-access MAF lists 130 somatic variants for this specimen: 80 protein-altering or splice-affecting, 30 silent, 20 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 65, Silent 30, Intron 12, Nonsense Mutation 6, RNA 5, 3'UTR 3, Frame Shift Del 2, Splice Region 2, Splice Site 2, In Frame Del 1, Nonstop Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID2 | c.2617G>C p.A873P | Missense Mutation (SNP) | VAF 31/196 reads (16%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.169); catalogued as COSV57614089; called by muse, mutect2, varscan2
- ATP13A5 | c.2509G>A p.E837K | Missense Mutation (SNP) | VAF 13/101 reads (13%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.909); catalogued as COSV100666040; called by muse, mutect2, varscan2
- DROSHA | c.3838G>C p.D1280H | Missense Mutation (SNP) | VAF 28/154 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV100757745; called by muse, mutect2
- EPHA6 | c.1126G>T p.G376* | Nonsense Mutation (SNP) | VAF 13/80 reads (16%) | catalogued as COSV67559476; called by muse, mutect2, varscan2
- GAB1 | c.110G>A p.R37H | Missense Mutation (SNP) | VAF 22/156 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746261423, COSV53759028; called by muse, mutect2
- GRM4 | c.689A>G p.Y230C | Missense Mutation (SNP) | VAF 24/316 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs928835239; called by muse, mutect2
- HECA | c.1208G>A p.R403Q | Missense Mutation (SNP) | VAF 39/267 reads (15%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.69); catalogued as rs774114464; called by muse, mutect2, varscan2
- LMBRD2 | c.901C>G p.P301A | Missense Mutation (SNP) | VAF 28/136 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV56951429; called by muse, mutect2, varscan2
- MACF1 | c.8582G>C p.R2861T | Missense Mutation (SNP) | VAF 17/105 reads (16%) | catalogued as COSV99244798; called by muse, mutect2, varscan2
- MROH2B | c.2590C>T p.R864* | Nonsense Mutation (SNP) | VAF 31/151 reads (21%) | catalogued as rs770970800, COSV68186527; called by muse, mutect2, varscan2
- MUC16 | c.23896G>C p.E7966Q | Missense Mutation (SNP) | VAF 21/197 reads (11%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.096); catalogued as rs941593282, COSV67447457; called by muse, mutect2, varscan2
- NCOA6 | c.5687C>T p.P1896L | Missense Mutation (SNP) | VAF 33/295 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs754575825, COSV100749886, COSV62869455; called by muse, mutect2, varscan2
- NLRP2 | c.266A>T p.K89M | Missense Mutation (SNP) | VAF 38/368 reads (10%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.779); catalogued as rs945026463; called by muse, mutect2
- NPBWR1 | c.77C>T p.A26V | Missense Mutation (SNP) | VAF 23/190 reads (12%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as rs764864940; called by muse, mutect2, varscan2
- NUMBL | c.1243C>T p.R415* | Nonsense Mutation (SNP) | VAF 97/211 reads (46%) | catalogued as COSV53284169; called by muse, mutect2, varscan2
- P2RX4 | c.357T>G p.I119M | Missense Mutation (SNP) | VAF 28/136 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.392); catalogued as COSV100078787; called by mutect2, varscan2
- PCSK2 | c.1879G>A p.V627M | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.992); catalogued as rs757047936; called by muse, mutect2, varscan2
- RTL9 | c.2674C>G p.P892A | Missense Mutation (SNP) | VAF 27/170 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV71825449; called by muse, mutect2, varscan2
- RYR2 | c.8764G>A p.A2922T | Missense Mutation (SNP) | VAF 32/214 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.267); catalogued as COSV63695329; called by muse, mutect2, varscan2
- SELENON | c.377A>G p.N126S | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated, low confidence (0.66); PolyPhen possibly damaging (0.621); catalogued as rs1053281657; called by muse, mutect2, varscan2
- SHISA2 | c.571G>A p.A191T | Missense Mutation (SNP) | VAF 27/157 reads (17%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.588); catalogued as rs114161425; called by muse, mutect2, varscan2
- TADA1 | c.359C>G p.S120* | Nonsense Mutation (SNP) | VAF 42/229 reads (18%) | catalogued as COSV63310271, COSV63310723; called by muse, mutect2, varscan2
- TDRD10 | c.694C>G p.Q232E | Missense Mutation (SNP) | VAF 34/188 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs760459283; called by muse, mutect2, varscan2
- TEKT4 | c.653G>A p.R218H | Missense Mutation (SNP) | VAF 18/178 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.042); catalogued as rs370925640; called by muse, mutect2
- TFEB | c.254A>T p.Q85L | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as COSV57825590; called by muse, mutect2, varscan2
- TP53 | c.370dup p.C124Lfs*25 | Frame Shift Ins (INS) | VAF 51/131 reads (39%) | catalogued as COSV52717910, COSV53118583; called by mutect2, pindel, varscan2
- TXNRD1 | c.1066G>A p.A356T (on ENST00000525566 / NM_001093771.3; = p.A258T on NM_003330.4) | Missense Mutation (SNP) | VAF 23/179 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs375808643; called by muse, mutect2, varscan2
- USH2A | c.3616A>G p.T1206A | Missense Mutation (SNP) | VAF 76/542 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.028); catalogued as rs1429873060; called by muse, mutect2, varscan2
- ZNF75A | c.722G>A p.G241E | Missense Mutation (SNP) | VAF 77/182 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs754220709; called by muse, mutect2, varscan2
- ABCB1 | c.1727C>A p.A576D | Missense Mutation (SNP) | VAF 37/188 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by mutect2, varscan2
- ADGRB3 | c.867T>A p.T289= | Splice Region (SNP) | VAF 18/62 reads (29%) | called by muse, mutect2, varscan2
- AKAP6 | c.2469+1G>A p.X823_splice | Splice Site (SNP) | VAF 12/39 reads (31%) | called by muse, mutect2
- ALS2CL | c.25C>G p.L9V | Missense Mutation (SNP) | VAF 10/103 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ATCAY | c.635_647+25del p.X212_splice | Splice Site (DEL) | VAF 11/116 reads (9%) | called by mutect2, pindel
- BRINP3 | c.1339T>C p.S447P | Missense Mutation (SNP) | VAF 21/163 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- C9orf72 | c.454G>A p.E152K | Missense Mutation (SNP) | VAF 24/120 reads (20%) | SIFT tolerated (0.8); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- CECR2 | c.688C>A p.Q230K (on ENST00000342247 / NM_001290047.2; = p.Q67K on NM_001290046.1) | Missense Mutation (SNP) | VAF 24/148 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.078); called by mutect2, varscan2
- CEP295 | c.5470G>T p.D1824Y | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- CLK3 | c.592A>G p.R198G (on ENST00000395066 / NM_001130028.1; = p.R50G on NM_003992.4) | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- CNOT10 | c.596A>G p.D199G | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- CNTNAP5 | c.178T>G p.W60G | Missense Mutation (SNP) | VAF 16/112 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- GIMAP7 | c.724T>C p.S242P | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT tolerated (0.38); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GJD2 | c.820C>T p.H274Y | Missense Mutation (SNP) | VAF 68/221 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GLI1 | c.3320_*41del | Nonstop Mutation (DEL) | VAF 6/10 reads (60%) | called by mutect2, varscan2
- GP6 | c.319G>C p.A107P | Missense Mutation (SNP) | VAF 109/452 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- IL10RA | c.679A>G p.T227A | Missense Mutation (SNP) | VAF 118/270 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- IL17RE | c.1066C>A p.Q356K | Missense Mutation (SNP) | VAF 35/225 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- IQGAP1 | c.4897A>G p.M1633V | Missense Mutation (SNP) | VAF 18/137 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); called by muse, mutect2, varscan2
- ITGA11 | c.1135G>C p.G379R | Missense Mutation (SNP) | VAF 14/139 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- JAK2 | c.863T>C p.I288T | Missense Mutation (SNP) | VAF 10/190 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.343); called by muse, mutect2
- KCNH8 | c.1223G>C p.G408A | Missense Mutation (SNP) | VAF 68/231 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- KRT4 | c.1441G>T p.G481W | Missense Mutation (SNP) | VAF 46/274 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LEMD1 | c.398A>C p.K133T (on ENST00000367151; = p.K86Q on NM_001001552.5) | Missense Mutation (SNP) | VAF 54/524 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- LRCH2 | c.434G>A p.C145Y | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- MYO9A | c.2378+7G>C | Splice Region (SNP) | VAF 6/47 reads (13%) | called by muse, varscan2
- MYOM1 | c.487G>A p.A163T | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NKX3-2 | c.758G>A p.W253* | Nonsense Mutation (SNP) | VAF 17/122 reads (14%) | called by muse, mutect2, varscan2
- OPTC | c.619A>T p.I207F | Missense Mutation (SNP) | VAF 58/416 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.439); called by mutect2, varscan2
- PDILT | c.1231A>T p.M411L | Missense Mutation (SNP) | VAF 40/96 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.278); called by mutect2, varscan2
- PGR | c.298A>T p.S100C | Missense Mutation (SNP) | VAF 42/274 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.811); called by mutect2, varscan2
- PLXNA2 | c.562G>A p.V188M | Missense Mutation (SNP) | VAF 39/278 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- PODN | c.1184A>G p.E395G (on ENST00000395871; = p.E347G on NM_153703.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 61/498 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- POSTN | c.2305G>T p.G769C | Missense Mutation (SNP) | VAF 50/227 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.75); called by mutect2, varscan2
- PRDM15 | c.1870del p.H624Tfs*34 | Frame Shift Del (DEL) | VAF 52/110 reads (47%) | called by mutect2, pindel, varscan2
- RBM33 | c.763G>T p.A255S | Missense Mutation (SNP) | VAF 26/155 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.224); called by muse, mutect2, varscan2
- SERPINI2 | c.136A>G p.I46V | Missense Mutation (SNP) | VAF 47/296 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SFTPB | c.655C>G p.Q219E | Missense Mutation (SNP) | VAF 53/311 reads (17%) | SIFT tolerated (0.36); PolyPhen benign (0.189); called by muse, mutect2, varscan2
- SP3 | c.1507_1527del p.G503_T509del | In Frame Del (DEL) | VAF 77/309 reads (25%) | called by mutect2, pindel, varscan2
- SPTB | c.2319G>C p.Q773H | Missense Mutation (SNP) | VAF 21/292 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- STING1 | c.913T>C p.S305P | Missense Mutation (SNP) | VAF 15/130 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.187); called by muse, mutect2
- TENM3 | c.5420del p.P1807Rfs*10 | Frame Shift Del (DEL) | VAF 20/118 reads (17%) | called by mutect2, pindel, varscan2
- TFDP2 | c.697C>T p.Q233* (on ENST00000489671 / NM_001178139.2; = p.Q173* on NM_006286.5) | Nonsense Mutation (SNP) | VAF 20/128 reads (16%) | called by muse, mutect2, varscan2
- TNR | c.637G>C p.V213L | Missense Mutation (SNP) | VAF 26/206 reads (13%) | SIFT tolerated (0.48); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- TPGS1 | c.485C>G p.A162G | Missense Mutation (SNP) | VAF 31/199 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.41); called by muse, mutect2, varscan2
- TRMT61B | c.901A>C p.S301R | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT tolerated (0.39); PolyPhen benign (0.199); called by muse, mutect2, varscan2
- TRPC4AP | c.670C>A p.L224I | Missense Mutation (SNP) | VAF 14/251 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); called by muse, mutect2
- ZFPM2 | c.287A>T p.D96V | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.093); called by muse, mutect2
- ZNF415 | c.803G>C p.G268A | Missense Mutation (SNP) | VAF 14/271 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.86); called by muse, mutect2
- ZNF728 | c.477T>A p.N159K | Missense Mutation (SNP) | VAF 21/434 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); called by muse, mutect2
- ZNF761 | c.1671G>C p.K557N | Missense Mutation (SNP) | VAF 26/347 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.772); called by muse, mutect2
- AATK | c.522G>A p.V174= (on ENST00000326724 / NM_001080395.3; = p.V71= on NM_004920.2) | Silent (SNP) | VAF 31/133 reads (23%) | called by muse, mutect2, varscan2
- ANPEP | c.1428C>T p.S476= | Silent (SNP) | VAF 16/156 reads (10%) | catalogued as rs1007215494; called by muse, mutect2
- C14orf132 | c.237G>A p.P79= (on ENST00000553782 / NM_001289139.2; = p.P48= on NM_001252507.3) | Silent (SNP) | VAF 63/370 reads (17%) | catalogued as rs973697475; called by muse, mutect2, varscan2
- CNR2 | c.576G>A p.L192= | Silent (SNP) | VAF 11/83 reads (13%) | called by muse, mutect2, varscan2
- COL3A1 | c.174A>T p.G58= | Silent (SNP) | VAF 36/430 reads (8%) | called by muse, mutect2
- CP | c.2334G>A p.K778= | Silent (SNP) | VAF 33/268 reads (12%) | called by muse, mutect2, varscan2
- CRPPA | c.52C>T p.L18= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as rs886043287; ClinVar: likely benign / uncertain significance; called by muse, mutect2
- DSCAML1 | c.5331C>T p.I1777= (on ENST00000321322; = p.I1717= on NM_020693.4) | Silent (SNP) | VAF 7/43 reads (16%) | catalogued as rs767828414, COSV58394395; called by muse, mutect2, varscan2
- EPHB2 | c.249C>A p.A83= | Silent (SNP) | VAF 20/140 reads (14%) | called by muse, mutect2, varscan2
- EPPK1 | c.6765G>A p.R2255= | Silent (SNP) | VAF 10/228 reads (4%) | called by muse, mutect2
- FCAMR | c.180C>T p.F60= | Silent (SNP) | VAF 13/87 reads (15%) | catalogued as rs369525141, COSV61367148; called by muse, mutect2, varscan2
- GLUD1 | c.219C>T p.F73= | Silent (SNP) | VAF 56/338 reads (17%) | catalogued as rs370668318; called by muse, mutect2, varscan2
- GRIK2 | c.1785C>T p.C595= | Silent (SNP) | VAF 20/166 reads (12%) | called by muse, mutect2, varscan2
- GRIN3A | c.1803G>A p.G601= | Silent (SNP) | VAF 84/549 reads (15%) | called by muse, mutect2, varscan2
- GTF2E1 | c.591G>A p.V197= | Silent (SNP) | VAF 55/378 reads (15%) | catalogued as COSV99381888; called by muse, mutect2, varscan2
- ISLR2 | c.1083G>A p.L361= | Silent (SNP) | VAF 33/253 reads (13%) | catalogued as rs969177426; called by muse, mutect2, varscan2
- KIF27 | c.3900A>T p.P1300= | Silent (SNP) | VAF 20/144 reads (14%) | called by muse, mutect2, varscan2
- MAP3K13 | c.270C>T p.H90= | Silent (SNP) | VAF 26/402 reads (6%) | catalogued as rs751270958; called by muse, mutect2
- MOGAT3 | c.474C>T p.R158= | Silent (SNP) | VAF 11/172 reads (6%) | catalogued as rs1272876600; called by muse, mutect2
- NLGN1 | c.1794C>T p.Y598= | Silent (SNP) | VAF 46/342 reads (13%) | catalogued as rs1484167435, COSV64328738; called by muse, mutect2, varscan2
- NTS | c.285C>T p.G95= | Silent (SNP) | VAF 120/237 reads (51%) | called by muse, mutect2, varscan2
- OTUD7A | c.501C>T p.I167= | Silent (SNP) | VAF 57/344 reads (17%) | catalogued as rs781738212; called by muse, mutect2, varscan2
- QSOX2 | c.1536C>T p.N512= | Silent (SNP) | VAF 16/136 reads (12%) | catalogued as rs781247114, COSV62393822; called by muse, mutect2, varscan2
- SLC13A5 | c.1290C>T p.S430= | Silent (SNP) | VAF 15/74 reads (20%) | catalogued as rs756166033, COSV53425022; ClinVar: likely benign; called by muse, mutect2, varscan2
- SPATA2L | c.1191G>A p.L397= | Silent (SNP) | VAF 9/65 reads (14%) | called by muse, mutect2, varscan2
- SPINK5 | c.804T>C p.R268= | Silent (SNP) | VAF 41/282 reads (15%) | called by muse, varscan2
- TEX35 | c.498A>C p.T166= | Silent (SNP) | VAF 48/375 reads (13%) | called by muse, mutect2, varscan2
- TICAM1 | c.459G>A p.G153= | Silent (SNP) | VAF 34/170 reads (20%) | called by muse, mutect2, varscan2
- TP73 | c.1800C>T p.G600= | Silent (SNP) | VAF 48/287 reads (17%) | catalogued as rs773643657; called by muse, mutect2, varscan2
- TSEN15 | c.78C>T p.D26= | Silent (SNP) | VAF 22/128 reads (17%) | catalogued as rs1167641203; called by muse, mutect2, varscan2
- AC024598.1 | c.1130-918T>A | Intron (SNP) | VAF 43/209 reads (21%) | called by mutect2, varscan2
- AC091163.2 | n.460-445C>T | Intron (SNP) | VAF 41/132 reads (31%) | catalogued as rs1198498639; called by muse, mutect2, varscan2
- ARRB1 | c.414+15G>A | Intron (SNP) | VAF 11/93 reads (12%) | called by muse, varscan2
- CLU | c.*703G>T | 3'UTR (SNP) | VAF 76/571 reads (13%) | catalogued as rs1384237429; called by muse, mutect2, varscan2
- CRELD2 | c.593-285C>T | Intron (SNP) | VAF 16/115 reads (14%) | catalogued as rs1569185061; called by muse, mutect2, varscan2
- DGCR2 | c.625+2401C>T | Intron (SNP) | VAF 4/38 reads (11%) | called by muse, mutect2
- FAM157B | n.386A>G | RNA (SNP) | VAF 15/90 reads (17%) | called by muse, varscan2
- GPAT4 | c.537-153C>T | Intron (SNP) | VAF 15/86 reads (17%) | called by muse, mutect2
- LINC02874 | n.461C>G | RNA (SNP) | VAF 30/270 reads (11%) | called by muse, mutect2, varscan2
- LRATD1 | c.*148C>T | 3'UTR (SNP) | VAF 7/60 reads (12%) | called by muse, mutect2, varscan2
- NOC2LP2 | n.520G>A | RNA (SNP) | VAF 28/424 reads (7%) | catalogued as rs572687066; called by muse, mutect2
- PMEPA1 | c.109+9328G>A | Intron (SNP) | VAF 50/247 reads (20%) | called by muse, mutect2, varscan2
- PMPCA | c.1408+215G>A | Intron (SNP) | VAF 29/76 reads (38%) | called by muse, mutect2
- PTGER3 | c.*24-12949T>C | Intron (SNP) | VAF 15/84 reads (18%) | called by muse, mutect2, varscan2
- RYR1 | c.10440+12G>T | Intron (SNP) | VAF 36/298 reads (12%) | called by muse, mutect2, varscan2
- SLC36A2 | c.843+774G>A | Intron (SNP) | VAF 18/132 reads (14%) | called by muse, mutect2, varscan2
- SPATA31C1 | n.1774A>C | RNA (SNP) | VAF 44/280 reads (16%) | called by mutect2, varscan2
- SSPOP | n.1093G>T | RNA (SNP) | VAF 15/61 reads (25%) | called by muse, mutect2, varscan2
- STXBP2 | c.1453-16G>C | Intron (SNP) | VAF 24/242 reads (10%) | called by muse, mutect2, varscan2
- XIAP | c.*6727T>G | 3'UTR (SNP) | VAF 15/157 reads (10%) | called by muse, mutect2, varscan2
